Surgical pathology report (de-identified scan), TCGA case TCGA-55-8091, project TCGA-LUAD (Lung Adenocarcinoma), tissue source site International Genomics Consortium, specimen TCGA-55-8091-01A (Primary Tumor).

[page 1 of 3]
SURGICAL PATHOLOGY:

PROCEDURE DATE: [REDACTED] RECEIVED DATE: [REDACTED] REPORT DATE: [REDACTED]

COPY TO:

IO Consultation

FS DIAGNOSES 1 AND 2: "Negative for neoplasm (reported to Dr. [REDACTED] positive patient ID)" by Dr. [REDACTED] campus

Pre-Op Diagnosis

Lung cancer

Post-Op Diagnosis

Same as above

Clinical History

Nothing indicated

Gross Description:

Six parts

Container labeled "[REDACTED] R lymph node" has 1.5 x 1.5 x 0.4 cm of gray-tan to yellow fleshy and fibrofatty tissue fragments which are submitted for frozen section and reported as "negative for neoplasm (reported to [REDACTED] positive patient ID)" by Dr. [REDACTED]. The frozen residue is submitted in a single cassette.

Container labeled "[REDACTED] L lymph node" has a 0.6 x 0.4 x 0.2 cm irregular fragment of soft gray-tan to pink tissue which is submitted for frozen section and reported as "negative for neoplasm (reported to [REDACTED] positive patient ID)" by Dr. [REDACTED]. The frozen residue is submitted in a single cassette.

Container labeled "[REDACTED] - station 11 lymph node" has a 2.2 x 1.2 x 0.8 cm lobulated fleshy red-brown to black nodule with a mottled fleshy gray-black cut surface. The sectioned specimen is entirely submitted in a single cassette.

Container labeled "[REDACTED] - station 12 lymph node" has a 1.0 x 0.7 x 0.6 cm fleshy tan-pink to brown-black nodule with a mottled fleshy brown-black cut surface. The bisected nodule is

[REDACTED]

[page 2 of 3]
entirely submitted in a single cassette.

Container labeled "[REDACTED] right lower lobe" has a previously partially sectioned recognizable portion of pulmonary parenchyma grossly consistent with right lower lobe of lung. The specimen as received weighs 313 grams and measures 15.2 x 10.5 x 5.5 cm. The margin of resection is a stapled bifurcated tertiary bronchus. The pleura is smooth and pink-red with moderate anthracotic streaking. On the lower medial aspect the specimen is sectioned to reveal a previously partially sectioned 2.0 x 2.0 x 1.6 cm subpleural nodular lesion with a gritty gray-tan fibrotic cut surface. This grossly extends to but not through the pleura on the medial aspect and is seen at its nearest point 1.1 cm from the basal pleura. The lesion is seen at its nearest point 2.8 cm from the bronchial margin. An apparent bronchial connection is identified. Noted on the lower outer aspect is a subpleural 0.8 x 0.7 x 0.6 cm subpleural nodular lesion which has a fibrotic cut surface and areas of calcification. The remaining parenchyma is spongy, slightly edematous, and tan-pink without additional lesions. Also received in the same container are three tissue cassettes each labeled "[REDACTED]". Representative sections are submitted labeled as follows: A - shaved bronchial margin; B-E - remaining lesion and surrounding tissue; F - lateral partially calcified nodule; G - random uninvolved parenchyma.

Container labeled "[REDACTED] station 7 lymph node" has two irregular fragments of soft gray-pink tissue, 0.8 x 0.6 x 0.3 cm each. Specimen entirely submitted in a single cassette.

[REDACTED]
Microscopic Description:
See diagnosis.

Final Diagnosis

4 R lymph node, biopsy with frozen section:

Lymph node with anthracotic pigment, negative for neoplasm, permanent sections confirm the frozen section diagnosis.

4 L lymph node, biopsy with frozen section:

Negative for neoplasm, permanent sections confirm the frozen section diagnosis.

Station 11 lymph node, biopsy:

Negative for neoplasm, extensive anthracotic pigment and reactive changes.

Station 12 lymph node, biopsy:

Negative for neoplasm.

Lung, right lower lobe, lobectomy:

Tumor characteristics:

Histologic type: Adenocarcinoma, moderately differentiated.

Tumor location: Subpleural right lower lung lobe.

Tumor size: 2.0 x 2.0 x 1.6 cm.

Tumor grade: Moderately differentiated.

Pleural invasion: Yes (tumor appears to focally involve overlying pleura in slide 5D).

Lymphovascular space invasion: No.

Surgical margin status:

Tumor distance from bronchial margin: 2.8 cm.

Tumor distance from stapled margin: Not applicable.

Tumor distance from pleural surface: Less than 0.5 cm, focally involving pleura

[REDACTED]

[page 3 of 3]
microscopically.
Lymph node status:
See specimens 1, 2, 3, 4 and 6.
Station 7 lymph node:
Negative for tumor. [REDACTED]

Stage: T2N0
[REDACTED]

Comments

This test has been finalized at the [REDACTED] Campus.

Original report signed out by Dr. [REDACTED]

REVISION:

This revision is made to add the staging to the Diagnosis Section.
There is no change in the original diagnosis.
[REDACTED]

<Sign Out Dr. Signature>

[REDACTED]

Source: NCI Genomic Data Commons file ea287e2e-8808-4ac2-95cd-9a12d40398ad (TCGA-55-8091.33902B19-5BE6-47FF-81A7-B945AE674A2F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).